Surgical pathology report (de-identified scan), TCGA case TCGA-ZN-A9VV, project TCGA-MESO (Mesothelioma), tissue source site Brigham and Women's Hospital Division of Thoracic Surgery, specimen TCGA-ZN-A9VV-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Report Status: Final

ICD O3

Mesothelioma, biphasic, malignant
9053/3

Site: Pleura NOS
C38.4

W 6/13/14

Procedure Date:

PATHOLOGIC DIAGNOSIS:

- A. RIB:
Fragments of rib(s) with maturing trilineage hematopoiesis,
negative for tumor.
- B. PORT SITE #1:
MALIGNANT MESOTHELIOMA (3.5 cm), involving fibrous tissue and invasive
into skeletal muscle.
- C. 2R:
METASTATIC MALIGNANT MESOTHELIOMA, involving one (1) lymph node.
- D. DIAPHRAGM:
Skeletal muscle and fibroadipose tissue, negative for tumor.
- E. LEVEL 7:
One (1) lymph node, negative for tumor.
- F. LEVEL 8:
Two (2) lymph nodes, negative for tumor .
- G. PLEURA AND DIAPHRAGM:
MALIGNANT MESOTHELIOMA, mixed epithelial and sarcomatoid type,
with exophytic papillary, macrocystic, tubulopapillary, and solid
features.
The largest tumor nodule is 14.2 cm, and the maximum thickness of the
tumor is 2.8 cm.
Tumor involves fibroadipose tissue and focally invades lung parenchyma.
Lymphovascular invasion identified.
- H. LEVEL 7 #2:
METASTATIC MALIGNANT MESOTHELIOMA, lymph node(s).
- I. 4R:
METASTATIC MALIGNANT MESOTHELIOMA involving lymph node.
- J. PORT SITE 1 #2:
Skin and subcutis with scar and foreign body giant cell reaction,
negative for tumor.
- K. PORT SITE #2:
Skin and fibroadipose tissue with scarring and foreign body giant
cell reaction, negative for tumor.
- L. RIGHT MIDDLE LOBE WEDGE:
MALIGNANT MESOTHELIOMA, involving visceral pleura.
Stapled resection margin, negative for tumor.

[page 2 of 3]
Pathology Report

TISSUE SUBMITTED:

A/1. Rib.
B/2. Port site #1.
C/3. 2R.
D/4. Diaphragm.
E/5. Level 7.
F/6. Level 8.
G/7. Pleura and diaphragm frozen section tumor bank.
H/8. Level 7 #2.
I/9. 4R.
J/10. Port site 1 #2.
K/11. Port site #2.
L/12. RML wedge.

GROSS DESCRIPTION:

The specimen is received fresh, in four parts, each labeled with the patient's name and medical record number.

Part A, "rib", consists of two fragments of rib (1.9 x 1.9 x 0.7 cm and 14.5 x 1.5 x 1.3 cm). No gross lesions are appreciated. A sample of bone marrow from each portion of rib is submitted.

Micro A1: Bone marrow from longer portion of rib, multi frags, RSS.

Micro A2: Bone marrow from shorter portion of rib, multi frags, RSS.

Part B, "port site #1", consists of a single fragment of tan/pink soft tissue (5.1 x 2.7 x 2.6 cm) with attached skeletal muscle (4.7 x 1.2 x 0.9 cm). The aspect of the specimen opposing the skeletal muscle is covered by a portion of tan/pink glistening fibromembranous tissue. A firm, rubbery, tan/white nodule (0.4 x 0.3 x 0.2 cm) is present on the surface. The specimen is serially sectioned to reveal a firm, tan/white, well-circumscribed nodule (3.5 x 2.4 x 1.9 cm), abutting but not invading into the skeletal muscle. Representative sections are submitted.

Micro B1-B2: Representative mass to skeletal muscle, 1 frag each, RSS.

Part C, "2R", consists of a single fragment of tan/pink/yellow soft tissue (3.3 x 1.4 x 0.9 cm), containing a single lymph node (1.1 x 0.8 x 0.5 cm), which is bisected and submitted in its entirety.

Micro C1: 2R lymph node, 2 frags, ESS.

Part D, "diaphragm", consists of two fragments of unoriented tan/pink/red skeletal muscle with attached fibroadipose tissue (1.1 x 0.7 x 0.6 and 2.5 x 1.3 x 0.6 cm), which are submitted in toto.

Micro D1: Diaphragm, 2 frags, ESS.

Part E, "level 7", consists of one fragment of tan/pink anthracotic soft tissue (1.0 x 0.5 x 0.3 cm), which is submitted in toto.

Micro E1: Level 7 lymph node, 1 frag, ESS.

Part F, "level 8", consists of a single fragment of tan/pink/white soft tissue (2.2 x 0.7 x 0.4 cm) with two lymph nodes (0.7 and 0.9 cm), which are submitted in toto.

Micro F1: Level 8 lymph nodes, 2 frags, ESS.

Part G, "pleura and diaphragm", consists of multiple irregular fragments of tan/pink soft tissue consistent with pleura (24.5 x 14.5 x 2.8 cm in aggregate) with attached skeletal muscle (12.5 x 11.2 x 2.1 cm in greatest dimension). There are multiple nodular, friable, tan/white, rubbery nodules present involving the pleura (ranging 0.1 cm to 14.2 cm, maximum thickness 2.8 cm). The largest nodule is present on the apparent lateral portion of the specimen.

[page 3 of 3]
Pathology Report

Sections through the nodules reveal multiple cystic spaces, focal papillary projections, and areas of gelatinous, friable tumor with hemorrhage consistent with necrosis. The tumor abuts but does not grossly invade through diaphragm. Representative sections are submitted.

Micro G1-G7: Representative tumor nodules to skeletal muscle and pleura, 1-2 frags each, RSS.

Part H, "level 7 #2", consists of three fragments of tan/pink anthracotic soft tissue (ranging 1.1 x 0.4 x 0.2 to 1.2 x 0.9 x 0.5 cm), which are submitted in

Micro H1: Level 7 node, 3 frags, ESS.

Part I, "4R", consists of a single fragment of tan/pink anthracotic soft tissue (1.2 x 0.6 x 0.4 cm), which is submitted in

Micro I1: 4R node, 1 frag, ESS.

Part J, "port site 1 #2", consists of a tan/white skin ellipse (2.0 x 0.9 cm) with underlying fibroadipose tissue (2.1 x 1.3 x 0.4 cm), which is submitted in

Micro J1: Port site #1 part 2, 1 frag, ESS.

Part K, "port site #2", consists of a tan/white skin ellipse with subcutis (2.3 x 0.9 x 0.5 cm) and a separate fragment of tan/red/yellow soft tissue (2.3 x 1.7 x 0.9 cm). A separate fragment of soft tissue is bisected. The entire specimen is submitted.

Micro K1: Skin, 1 frag, ESS.

Micro K2: Soft tissue, bisected, 2 frags, ESS.

Part L, "RML wedge", consists of a severely disrupted pulmonary wedge resection (5.7 x 1.3 x 1.2 cm) with a stapled resection margin (5.7 cm, blue). The entire specimen is submitted.

Micro L1-L2: Right middle lobe, 2 frags each, ESS.

[REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[REDACTED]

Source: NCI Genomic Data Commons file f73450bd-ad62-4acb-a103-f99c7bb85316 (TCGA-ZN-A9VV.E6BF6C0B-1B9E-42A3-964F-5F9A12817496.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).